Somatic mutation profile of tumor specimen TCGA-AF-2692-01A (aliquot TCGA-AF-2692-01A-01D-1989-10) from TCGA case TCGA-AF-2692, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54.3 years (19,830 days).
Specimen TCGA-AF-2692-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c19f2cd5-2634-4376-8f83-44f7de6f8958.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-2692-10A (Blood Derived Normal), aliquot TCGA-AF-2692-10A-01D-1989-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17588093-5933-4bb0-a411-c4d6f12d4fb9

The open-access MAF lists 19 somatic variants for this specimen: 10 protein-altering or splice-affecting, 9 silent.
By variant classification: Silent 9, Missense Mutation 8, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMK2A | c.1120G>A p.D374N (on ENST00000348628 / NM_171825.2; = p.D385N on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/395 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.183); catalogued as COSV62245757, COSV62246315; called by muse, mutect2
- EZHIP | c.1097C>A p.A366D | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.726); catalogued as COSV100539621; called by muse, mutect2, varscan2
- GCN1 | c.5380C>T p.R1794C | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1459990599, COSV56105039; called by muse, mutect2, varscan2
- KCNG4 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537957795, COSV100376995; called by muse, mutect2, varscan2
- PCDHA5 | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV100972222, COSV100972443; called by muse, mutect2, varscan2
- PFN3 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1389425855, COSV99499586; called by muse, mutect2, varscan2
- RBMXL2 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.135); catalogued as rs754785233, COSV60978896; called by muse, mutect2, varscan2
- REEP6 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 241/446 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148789777; called by muse, mutect2, varscan2
- UNC5A | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as COSV56167326; called by muse, mutect2, varscan2
- DNAJA3 | c.181_183dup p.L61dup | In Frame Ins (INS) | VAF 38/85 reads (45%) | called by mutect2, varscan2
- ABCC5 | c.2055G>T p.L685= | Silent (SNP) | VAF 49/193 reads (25%) | catalogued as COSV99656713, COSV99657523; called by muse, mutect2, varscan2
- B4GALNT4 | c.2091C>T p.R697= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100327406; called by muse, mutect2
- ESX1 | c.372G>A p.A124= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV101006429; called by muse, mutect2, varscan2
- MN1 | c.3087C>T p.D1029= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs1177422258, COSV56557674; called by muse, mutect2, varscan2
- MYLK2 | c.111C>T p.G37= | Silent (SNP) | VAF 43/157 reads (27%) | catalogued as rs1389317242, COSV101044743; called by muse, mutect2, varscan2
- SURF1 | c.504C>T p.C168= | Silent (SNP) | VAF 72/184 reads (39%) | catalogued as COSV100034650; called by muse, mutect2, varscan2
- TRIM56 | c.1953G>A p.S651= | Silent (SNP) | VAF 55/179 reads (31%) | catalogued as rs779628946, COSV100047188; called by muse, varscan2
- XKR4 | c.48C>T p.D16= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs1219724103, COSV100532029; called by muse, mutect2, varscan2
- ZNF653 | c.1413C>T p.Y471= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as rs377497436; called by muse, mutect2, varscan2
